Somatic mutation profile of tumor specimen TCGA-39-5021-01A (aliquot TCGA-39-5021-01A-01D-1441-08) from TCGA case TCGA-39-5021, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 70.9 years (25,895 days).
Specimen TCGA-39-5021-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6551a23-35dd-4589-bb9a-6086399f1196.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-39-5021-11A (Solid Tissue Normal), aliquot TCGA-39-5021-11A-01D-1441-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99159f2c-af26-4728-bd3f-af7c54cb5af8

The open-access MAF lists 152 somatic variants for this specimen: 105 protein-altering or splice-affecting, 45 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 45, Nonsense Mutation 7, Frame Shift Del 5, Splice Site 2, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.423C>G p.C141W | Missense Mutation (SNP) | VAF 26/66 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519977, COSV52671863, COSV52706449, COSV52741627, COSV52827803; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA10 | c.503T>A p.V168E | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV52230815; called by muse, mutect2, varscan2
- ABCA4 | c.5320G>A p.V1774I | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.246); catalogued as COSV64679344; called by muse, mutect2, varscan2
- ACOXL | c.757G>C p.G253R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61331823; called by muse, mutect2, varscan2
- ADAD1 | c.1264A>G p.S422G | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs1025994056, COSV56647963; called by muse, mutect2, varscan2
- ADCY6 | c.1922G>T p.R641L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV100327018; called by muse, mutect2, varscan2
- ANKRD30A | c.3856A>T p.R1286* (on ENST00000611781; = p.R1230* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV64623572; called by muse, mutect2, varscan2
- ARHGAP20 | c.3110G>T p.W1037L | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV52820616; called by muse, mutect2, varscan2
- ARHGAP31 | c.2645T>G p.V882G | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV51800391; called by muse, mutect2, varscan2
- ARMC1 | c.447A>G p.I149M | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV52535087; called by muse, mutect2, varscan2
- ATP10B | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.417); catalogued as COSV58781325; called by muse, varscan2
- AXDND1 | c.1290G>C p.W430C | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100858419, COSV62650338; called by muse, mutect2, varscan2
- BBS12 | c.319G>T p.V107F | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV58563287; called by muse, mutect2, varscan2
- BBS12 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | catalogued as COSV58561003, COSV58563296; called by muse, mutect2, varscan2
- BCAR1 | c.2240A>G p.Y747C | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50809433; called by muse, mutect2, varscan2
- BCL6 | c.1880A>G p.E627G | Missense Mutation (SNP) | VAF 92/344 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51656350; called by muse, mutect2, varscan2
- CAMK2B | c.354G>T p.Q118H | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.02); catalogued as COSV51667624; called by muse, mutect2, varscan2
- CCDC191 | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV55677156; called by muse, mutect2, varscan2
- CCDC74A | c.432G>T p.R144S | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.765); catalogued as COSV54609528; called by muse, mutect2, varscan2
- CD19 | c.553A>C p.S185R | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as COSV61190028; called by muse, varscan2
- CEP85L | c.652A>G p.I218V | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV63829451; called by muse, mutect2
- CFAP61 | c.2677del p.A893Pfs*70 | Frame Shift Del (DEL) | VAF 42/130 reads (32%) | catalogued as COSV55646813; called by mutect2, pindel, varscan2
- CHD3 | c.284A>G p.Y95C | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs777077851, COSV57881378; called by muse, mutect2
- CKAP5 | c.2953G>A p.E985K | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as COSV56375201; called by muse, mutect2, varscan2
- CLTC | c.857A>T p.D286V | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52253956; called by muse, mutect2, varscan2
- COL2A1 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as rs1382133199, COSV61535267; called by muse, mutect2, varscan2
- CSMD1 | c.6148C>A p.L2050I (on ENST00000520002; = p.L2049I on NM_033225.6) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.994); catalogued as COSV59396364; called by muse, mutect2
- CTNND1 | c.1415T>G p.I472S | Missense Mutation (SNP) | VAF 73/281 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV62386674; called by muse, mutect2, varscan2
- CUL3 | c.2029+1G>A p.X677_splice | Splice Site (SNP) | VAF 25/156 reads (16%) | catalogued as COSV52369424; called by muse, mutect2, varscan2
- CUL3 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52366847; called by muse, mutect2, varscan2
- CUZD1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV59028518; called by muse, mutect2, varscan2
- DCLRE1C | c.99C>G p.H33Q | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63185986; called by muse, mutect2, varscan2
- DDX27 | c.317G>A p.S106N | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs763129675, COSV65631148; called by muse, varscan2
- DPP10 | c.1990G>T p.D664Y | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.56); catalogued as COSV59739442; called by muse, mutect2, varscan2
- ELOA2 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.19); catalogued as COSV55300898; called by muse, mutect2, varscan2
- EYS | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.788); catalogued as COSV61002234; called by muse, mutect2, varscan2
- FAM20B | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 74/267 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV55383059; called by muse, mutect2, varscan2
- FAP | c.1183T>C p.W395R | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51868528; called by muse, mutect2, varscan2
- FARSA | c.911G>A p.G304D | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.404); catalogued as COSV58906258; called by muse, mutect2, varscan2
- FCRL5 | c.2007G>T p.Q669H | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as rs199994796, COSV100709323, COSV62521193; called by muse, mutect2, varscan2
- GDF15 | c.467A>C p.H156P | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV53251853; called by muse, mutect2, varscan2
- GUK1 | c.410G>C p.R137P | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57158579; called by muse, mutect2, varscan2
- HEY1 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV61233846; called by muse, varscan2
- IMPG1 | c.1061A>C p.D354A | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as COSV64062677; called by muse, mutect2, varscan2
- ISG20L2 | c.847A>T p.T283S | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57461500; called by muse, mutect2, varscan2
- ITPKB | c.2762G>C p.R921P | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55271318; called by muse, mutect2, varscan2
- KCNA5 | c.1407C>A p.D469E | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.761); catalogued as rs768740011, CM1212184, COSV52907745, COSV52909252; called by muse, mutect2, varscan2
- KIRREL2 | c.1523C>A p.T508N | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.212); catalogued as COSV99384565; called by mutect2, varscan2
- KLHL4 | c.2081G>T p.R694I | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs745792102, COSV64140751; called by muse, mutect2, varscan2
- LRFN2 | c.1149C>G p.S383R | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.482); catalogued as COSV57835828; called by muse, mutect2, varscan2
- MANEA | c.874A>T p.N292Y | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as COSV62590823; called by muse, varscan2
- MCM3 | c.1042del p.D348Tfs*6 (on ENST00000229854 / NM_001366374.2; = p.D338Tfs*6 on NM_002388.6 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 36/158 reads (23%) | catalogued as rs780738128; called by mutect2, varscan2
- MGAT3 | c.667G>T p.V223L | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.402); catalogued as rs775323171, COSV57869092; called by muse, mutect2, varscan2
- MRPL58 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV56902058; called by muse, mutect2, varscan2
- MS4A14 | c.553C>A p.Q185K | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV55738971; called by muse, mutect2, varscan2
- MYH2 | c.4268C>A p.T1423K | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55450621, COSV99820693; called by muse, mutect2, varscan2
- NADSYN1 | c.1201A>G p.T401A | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.217); catalogued as COSV59815636; called by muse, mutect2, varscan2
- NAV2 | c.1583C>T p.A528V (on ENST00000396087 / NM_001244963.2; = p.A505V on NM_145117.5) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV62338060; called by muse, mutect2, varscan2
- NLRP7 | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 15/91 reads (16%) | catalogued as COSV60176850; called by muse, mutect2
- NOTUM | c.767C>A p.A256D | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.243); catalogued as COSV68826807; called by muse, mutect2, varscan2
- NUMA1 | c.5167G>C p.D1723H | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59645153; called by muse, mutect2, varscan2
- OR4B1 | c.451T>G p.F151V | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.213); catalogued as COSV58884302; called by muse, mutect2, varscan2
- OR4K5 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 55/728 reads (8%) | catalogued as COSV60005258, COSV60005593; called by muse, mutect2
- OR6N1 | c.595G>T p.D199Y | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58647870; called by muse, mutect2, varscan2
- PAPPA2 | c.4351G>T p.G1451W | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100868805; called by muse, mutect2, varscan2
- PCDH10 | c.199A>T p.N67Y | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52105948; called by muse, mutect2, varscan2
- PDCD1 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764200391, COSV57692360; called by muse, mutect2, varscan2
- PLB1 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV59837603; called by muse, mutect2, varscan2
- POLD1 | c.1325G>T p.G442V | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101486942; called by mutect2, varscan2
- PRICKLE1 | c.1118G>T p.R373L | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.94); PolyPhen benign (0.084); catalogued as COSV61547455; called by muse, mutect2, varscan2
- PRX | c.1547G>T p.R516L | Missense Mutation (SNP) | VAF 58/264 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV99398160; called by muse, varscan2
- RB1 | c.264G>T p.L88F | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.272); catalogued as CS057979, COSV57305237, COSV57313037, COSV57330181; called by muse, mutect2, varscan2
- RIMS2 | c.1676C>A p.A559E (on ENST00000666250 / NM_001348490.2; = p.A367E on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.744); catalogued as COSV51682440, COSV51731865; called by muse, mutect2, varscan2
- ROR2 | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.481); catalogued as COSV65221658; called by muse, mutect2, varscan2
- RP1L1 | c.3248C>A p.T1083K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.496); catalogued as COSV66761302; called by muse, mutect2, varscan2
- RYR2 | c.6505G>T p.E2169* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as COSV63664965, COSV63720100; called by muse, mutect2, varscan2
- SAMSN1 | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53467361, COSV53478772; called by muse, mutect2, varscan2
- SEC23B | c.1754A>T p.H585L | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV52724595; called by muse, mutect2, varscan2
- SLC22A12 | c.1608G>C p.K536N | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.153); catalogued as COSV55465046; called by muse, mutect2
- SNX17 | c.370A>T p.S124C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV52011293; called by muse, mutect2, varscan2
- SRSF11 | c.448-1G>T p.X150_splice | Splice Site (SNP) | VAF 40/191 reads (21%) | catalogued as COSV63937960; called by muse, mutect2, varscan2
- SYT7 | c.915C>A p.Y305* | Nonsense Mutation (SNP) | VAF 13/129 reads (10%) | catalogued as COSV55653902, COSV55660189; called by muse, mutect2, varscan2
- TAS2R16 | c.614A>G p.K205R | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV50797253; called by muse, mutect2, varscan2
- TCTN1 | c.1118C>T p.P373L (on ENST00000551590 / NM_001173975.3; = p.P359L on NM_024549.6) | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66542877; called by muse, varscan2
- TEK | c.441G>C p.L147F | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.1); catalogued as COSV66236070; called by muse, mutect2, varscan2
- TENM4 | c.2707G>T p.G903C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV53678835; called by muse, mutect2, varscan2
- TEX47 | c.129G>T p.K43N | Missense Mutation (SNP) | VAF 36/241 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51878596, COSV99787267; called by muse, mutect2, varscan2
- TKTL2 | c.1364C>A p.A455D | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54921742; called by muse, mutect2, varscan2
- TMEM37 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs772027165, COSV50027516; called by muse, mutect2, varscan2
- TTN | c.34543G>A p.V11515I (on ENST00000591111; = p.V10588I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/135 reads (13%) | PolyPhen benign (0); catalogued as rs767090806, COSV60403892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUT7 | c.4460C>T p.S1487L | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV52899519; called by muse, mutect2, varscan2
- TYR | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.999); catalogued as COSV54488139; called by muse, mutect2
- VIM | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.1); catalogued as COSV56408234; called by muse, mutect2
- VPS13A | c.3850G>T p.D1284Y | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs527383410, COSV62440904; called by muse, varscan2
- VWA3B | c.2304C>A p.H768Q | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.231); catalogued as rs377557539, COSV68247509; called by mutect2, varscan2
- ZDBF2 | c.5779C>A p.P1927T | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV65628945; called by muse, mutect2, varscan2
- ZDBF2 | c.5780C>A p.P1927H | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV65630790; called by muse, mutect2, varscan2
- ZEB1 | c.847T>C p.Y283H | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58056891; called by muse, mutect2, varscan2
- ZNF80 | c.330C>A p.C110* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV57362900; called by muse, mutect2
- ZNF99 | c.1581T>A p.H527Q | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV68056061; called by muse, mutect2, varscan2
- MAGEA10 | c.101T>G p.V34G | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.296); called by muse, varscan2
- SNTA1 | c.608del p.G203Afs*15 | Frame Shift Del (DEL) | VAF 42/132 reads (32%) | called by mutect2, pindel, varscan2
- SPDEF | c.756del p.W252Cfs*49 | Frame Shift Del (DEL) | VAF 49/262 reads (19%) | called by mutect2, pindel, varscan2
- TRAV23DV6 | c.331G>C p.G111R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- ZNF236 | c.2978del p.K993Sfs*28 | Frame Shift Del (DEL) | VAF 28/174 reads (16%) | called by pindel, varscan2
- A2M | c.1734C>G p.L578= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV59385074; called by muse, mutect2, varscan2
- ABCA7 | c.2916T>C p.P972= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV54038611; called by muse, mutect2
- ADCYAP1R1 | c.765G>T p.L255= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV58447851; called by muse, mutect2, varscan2
- ALG5 | c.24G>A p.L8= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV53507814; called by muse, mutect2, varscan2
- ASTN1 | c.2487C>T p.L829= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV56089554; called by muse, mutect2, varscan2
- ASTN2 | c.786C>G p.P262= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV57823762; called by muse, varscan2
- B3GNT3 | c.891T>C p.D297= | Silent (SNP) | VAF 85/295 reads (29%) | catalogued as COSV57954366; called by muse, mutect2, varscan2
- CD19 | c.552C>A p.L184= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV61190011; called by muse, varscan2
- CSMD3 | c.4425A>T p.P1475= (on ENST00000297405 / NM_001363185.1; = p.P1371= on NM_052900.3) | Silent (SNP) | VAF 32/125 reads (26%) | catalogued as COSV52291132, COSV52345839; called by muse, mutect2, varscan2
- CUZD1 | c.54G>A p.L18= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV59028532; called by muse, mutect2, varscan2
- DHDH | c.447G>T p.V149= | Silent (SNP) | VAF 25/131 reads (19%) | catalogued as COSV55483677; called by muse, mutect2, varscan2
- EHD3 | c.468G>A p.G156= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs138864640, COSV59033357; called by muse, mutect2, varscan2
- F5 | c.4047C>A p.S1349= | Silent (SNP) | VAF 66/296 reads (22%) | catalogued as COSV63122235, COSV63129390; called by muse, varscan2
- F9 | c.123G>C p.L41= | Silent (SNP) | VAF 13/170 reads (8%) | catalogued as COSV54382819; called by muse, mutect2
- FAM43B | c.219C>T p.T73= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as rs1398680097, COSV100261566; called by muse, mutect2
- FASLG | c.294C>A p.G98= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV60681133; called by muse, mutect2, varscan2
- FRMPD4 | c.1698A>G p.Q566= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as COSV66224921; called by muse, mutect2, varscan2
- GGCX | c.996C>T p.P332= | Silent (SNP) | VAF 27/167 reads (16%) | catalogued as COSV52090838, COSV99290073; called by muse, mutect2, varscan2
- GLCCI1 | c.723A>G p.L241= | Silent (SNP) | VAF 21/128 reads (16%) | catalogued as COSV56205974; called by muse, mutect2, varscan2
- INSYN2A | c.963G>A p.Q321= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as COSV54763973; called by muse, mutect2, varscan2
- KALRN | c.4458G>T p.P1486= | Silent (SNP) | VAF 28/158 reads (18%) | catalogued as COSV53782779; called by muse, mutect2, varscan2
- KIAA1755 | c.3063G>C p.V1021= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV54081731; called by muse, mutect2, varscan2
- KLHDC2 | c.639A>G p.K213= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV53588633; called by muse, mutect2, varscan2
- LEMD3 | c.1266C>T p.L422= | Silent (SNP) | VAF 37/179 reads (21%) | catalogued as COSV57654511; called by muse, mutect2, varscan2
- LTBP1 | c.4623G>T p.V1541= (on ENST00000404816 / NM_206943.4; = p.V1215= on NM_000627.4) | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as COSV99699025; called by muse, mutect2, varscan2
- MAP1B | c.3948G>A p.K1316= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV57107664; called by muse, mutect2, varscan2
- MUC16 | c.23661C>T p.T7887= | Silent (SNP) | VAF 37/134 reads (28%) | catalogued as rs768793263, COSV67458761; called by muse, mutect2, varscan2
- NFATC1 | c.1308C>G p.S436= | Silent (SNP) | VAF 48/149 reads (32%) | catalogued as COSV53710872; called by muse, mutect2, varscan2
- NRXN2 | c.4968C>T p.A1656= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV55465060; called by muse, mutect2, varscan2
- NT5E | c.684C>A p.L228= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as COSV57630787; called by muse, mutect2, varscan2
- OR2C3 | c.87C>T p.F29= | Silent (SNP) | VAF 34/109 reads (31%) | catalogued as COSV63575887; called by muse, mutect2, varscan2
- OR4F17 | c.42G>A p.Q14= | Silent (SNP) | VAF 48/1295 reads (4%) | catalogued as COSV58842150; called by muse, mutect2
- OR8G5 | c.480A>T p.I160= | Silent (SNP) | VAF 35/288 reads (12%) | catalogued as COSV100422718; called by muse, mutect2, varscan2
- PAPPA2 | c.4098G>T p.S1366= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as COSV62814247; called by muse, mutect2, varscan2
- PMEL | c.231G>A p.L77= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as rs188708664, COSV62430374; called by muse, mutect2, varscan2
- POTEE | c.201C>T p.H67= | Silent (SNP) | VAF 62/324 reads (19%) | catalogued as rs1256036260, COSV58247166; called by muse, mutect2, varscan2
- SEC24C | c.496C>T p.L166= | Silent (SNP) | VAF 28/220 reads (13%) | catalogued as COSV59545561; called by muse, mutect2, varscan2
- SMYD3 | c.252G>A p.K84= (on ENST00000490107 / NM_001375962.1; = p.K25= on NM_022743.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/231 reads (13%) | catalogued as COSV66457649; called by muse, mutect2, varscan2
- SOCS2 | c.534C>T p.I178= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV61392716; called by muse, mutect2, varscan2
- TMEM51 | c.456G>A p.P152= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as rs752414813, COSV65690241, COSV65691312; called by muse, mutect2, varscan2
- UNC5D | c.2829C>T p.A943= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs1197380277, COSV54843057; called by muse, mutect2, varscan2
- XIRP2 | c.1101C>A p.A367= (on ENST00000628543; = p.A542= on NM_152381.6) | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV54739997; called by muse, mutect2, varscan2
- XIRP2 | c.1102C>A p.R368= (on ENST00000628543; = p.R543= on NM_152381.6) | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV99748890; called by muse, mutect2, varscan2
- XPNPEP2 | c.789T>C p.Y263= | Silent (SNP) | VAF 32/237 reads (14%) | catalogued as COSV64368277; called by muse, mutect2, varscan2
- ZNF585B | c.1083G>A p.K361= | Silent (SNP) | VAF 10/201 reads (5%) | catalogued as COSV57217325; called by muse, mutect2
- AL109984.1 | n.186+1651C>A | Intron (SNP) | VAF 12/41 reads (29%) | catalogued as COSV63755277; called by muse, mutect2, varscan2
- SSPOP | n.8659C>T | RNA (SNP) | VAF 8/52 reads (15%) | catalogued as COSV65139077; called by muse, mutect2, varscan2
